FM case AD32 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Squamous Cell Neoplasms.
https://portal.gdc.cancer.gov/cases/84b2e55f-5c57-42aa-95e0-1ad2b50b59de

Male, 55.2 years: Squamous cell carcinoma, NOS (ICD-O-3 8070/3). Tumor nuclei on the sequenced sample's slide: 30% (pathologist estimate recorded by GDC). Sample type: Tumor.
